Somatic mutation profile of tumor specimen TCGA-L5-A4OE-01A (aliquot TCGA-L5-A4OE-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 81.0 years (29,591 days).
Specimen TCGA-L5-A4OE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd01a2f-e561-4668-bbb4-c9759fc2e13b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OE-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OE-11A-11D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91fe6936-d3a2-41e2-a12e-3312f5605b5e

The open-access MAF lists 333 somatic variants for this specimen: 246 protein-altering or splice-affecting, 79 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 79, Nonsense Mutation 27, 3'Flank 3, Intron 3, Frame Shift Del 3, Splice Site 3, Splice Region 2, 3'UTR 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs377767375, CM057959, COSV61686903, COSV61687849, COSV61690865; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.1889C>A p.S630* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs1203828880; called by muse, mutect2, varscan2
- ADAMTS5 | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.392); catalogued as rs368781824; called by mutect2, varscan2
- ALOX12B | c.1787C>A p.P596Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100046628; called by muse, mutect2, varscan2
- ARID1A | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 24/39 reads (62%) | catalogued as COSV61372099; called by muse, mutect2, varscan2
- ASIC2 | c.811T>C p.F271L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as rs1390468271; called by muse, mutect2, varscan2
- ATP11A | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.142); catalogued as rs745600009, COSV52107786; called by muse, mutect2, varscan2
- BBS7 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.109); catalogued as rs757531986; called by muse, mutect2, varscan2
- BCKDHA | c.853+2T>C p.X285_splice | Splice Site (SNP) | VAF 19/36 reads (53%) | catalogued as rs558254502; called by muse, mutect2, varscan2
- BRIP1 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV51998946; called by muse, mutect2, varscan2
- BTNL9 | c.318G>T p.L106F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.209); catalogued as rs1186218401; called by muse, mutect2, varscan2
- C3orf33 | c.254G>A p.R85Q (on ENST00000340171 / NM_001308229.2; = p.R42Q on NM_173657.2) | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs547864770, COSV60896792; called by muse, mutect2, varscan2
- CAPRIN1 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs747560213; called by muse, mutect2, varscan2
- CASP7 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs555949483, COSV61883167; called by muse, mutect2, varscan2
- CCDC8 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs765306809, COSV56772548, COSV56774468; called by muse, mutect2, varscan2
- CCDC80 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV52817331; called by muse, mutect2, varscan2
- CCDC85A | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV68151248; called by muse, mutect2, varscan2
- CDHR3 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs776963823; called by mutect2, varscan2
- CHM | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs771806748; called by muse, mutect2, varscan2
- CMYA5 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs1256887140; called by muse, mutect2, varscan2
- CPNE6 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs892666560; called by muse, mutect2
- CSNK1A1L | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV65789552; called by muse, mutect2, varscan2
- CXCR2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV59280121; called by muse, mutect2, varscan2
- DEGS2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1490294231, COSV59785386; called by muse, mutect2, varscan2
- DGKH | c.2306G>T p.C769F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54931877; called by muse, mutect2, varscan2
- DKK2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53394554; called by muse, mutect2, varscan2
- DNER | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486878125, COSV100518774; called by muse, mutect2, varscan2
- DOCK3 | c.6014G>A p.R2005H | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1409009150; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100766100; called by muse, mutect2, varscan2
- EPB41L4A | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766314158; ClinVar: uncertain significance; called by mutect2, varscan2
- ERBB4 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53524670, COSV99631378; called by muse, mutect2, varscan2
- FAM171A1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767603375; called by muse, mutect2, varscan2
- FAM47C | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs199727942, COSV63723857; called by muse, mutect2
- GIMAP7 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs764216565; called by muse, mutect2, varscan2
- GMPS | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749180762, COSV55811075; called by muse, mutect2, varscan2
- GRIN3A | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs142779054, COSV62450125, COSV62452376, COSV62457978; called by muse, mutect2, varscan2
- HEPH | c.1994_1995del p.V665Afs*25 (on ENST00000343002; = p.V398Afs*25 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as rs1569324227; called by pindel, varscan2
- HIP1R | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs372462877; called by muse, mutect2, varscan2
- HMCN1 | c.13154G>T p.R4385I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54873650; called by muse, varscan2
- IQSEC1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1285176495, COSV56223381, COSV56224933; called by muse, mutect2, varscan2
- KAZN | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.078); catalogued as rs767387886; called by muse, mutect2, varscan2
- KCNJ6 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55710318; called by muse, mutect2, varscan2
- KIAA1755 | c.3487C>A p.P1163T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as COSV54073287; called by muse, mutect2, varscan2
- KIF1C | c.2720G>A p.R907H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs199975737; called by muse, mutect2
- KIF5A | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs140917012; called by muse, mutect2, varscan2
- KIF5A | c.2993G>C p.G998A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); catalogued as COSV54054975; called by muse, mutect2, varscan2
- KLHL17 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58531443; called by muse, mutect2, varscan2
- LGR5 | c.2523G>T p.W841C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV57004987, COSV57011235; called by muse, mutect2, varscan2
- LHCGR | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54292805; called by muse, mutect2
- LRRC32 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1267228327, COSV99477254; called by muse, mutect2, varscan2
- LRRC4B | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65349415; called by muse, mutect2, varscan2
- LRSAM1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs758867006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LSM14B | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs773531018; called by muse, mutect2, varscan2
- MAP4K3 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs932853814; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs368904071, COSV99571431; called by muse, mutect2
- MFSD11 | c.1173C>A p.F391L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV60629265; called by muse, mutect2, varscan2
- MTCL1 | c.2572G>A p.E858K (on ENST00000306329 / NM_001378206.1; = p.E498K on NM_015210.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.103); catalogued as rs774375780, COSV60405021; called by muse, mutect2, varscan2
- NCOR2 | c.3775C>T p.R1259W | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373295499; called by muse, mutect2, varscan2
- NECAB1 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as rs1433479859; called by muse, mutect2
- NRG3 | c.1339A>C p.S447R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64579994; called by muse, mutect2, varscan2
- OBSCN | c.7265G>T p.G2422V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs755928557; called by muse, mutect2, varscan2
- OBSCN | c.9304C>T p.L3102F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1268770090; called by muse, mutect2, varscan2
- OR11L1 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV63313847; called by muse, mutect2, varscan2
- OR2G2 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV100190005, COSV60739800; called by muse, mutect2, varscan2
- OR5J2 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV56620321; called by muse, mutect2, varscan2
- PPL | c.4423C>A p.L1475I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs751026334; called by muse, mutect2, varscan2
- PPP1R12C | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs34972456; called by muse, mutect2, varscan2
- PRAMEF2 | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs756763905; called by muse, mutect2, varscan2
- PTK2B | c.2475G>T p.E825D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV57752833; called by muse, mutect2, varscan2
- PTPN3 | c.1443C>A p.F481L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs774607981; called by muse, mutect2, varscan2
- RFX6 | c.2536G>T p.D846Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV60586774; called by muse, mutect2, varscan2
- RNPS1 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV57047686; called by muse, mutect2, varscan2
- RPS6KA5 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs780918760, COSV56222068, COSV56224010; called by muse, mutect2, varscan2
- RYR2 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs763802687, COSV63703359; called by muse, mutect2, varscan2
- SEZ6L2 | c.1078C>T p.R360C (on ENST00000308713 / NM_001114099.3; = p.R290C on NM_012410.4) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs201034422; called by muse, mutect2, varscan2
- SHMT2 | c.1378A>G p.S460G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1339726314; called by muse, mutect2, varscan2
- SIGLEC1 | c.3997C>T p.R1333C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs745782224, COSV99163682; called by muse, mutect2, varscan2
- SLC26A4 | c.1625C>A p.P542H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as CM097536; called by muse, mutect2, varscan2
- SLC27A6 | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1198468752; called by muse, mutect2, varscan2
- SLX4 | c.4976C>A p.P1659H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs762172434; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs746109620; called by mutect2, varscan2
- SPTBN5 | c.7769G>A p.R2590H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs773933741; called by muse, mutect2, varscan2
- SRCAP | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99349945; called by muse, mutect2, varscan2
- SRCIN1 | c.3268C>T p.R1090C (on ENST00000621492; = p.R1056C on NM_025248.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1466322341; called by muse, mutect2, varscan2
- SRGAP3 | c.2281C>A p.R761S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV64532959; called by muse, mutect2, varscan2
- ST18 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99387711; called by muse, mutect2, varscan2
- STAT1 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV63116212; called by muse, mutect2, varscan2
- SYP | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54296933; called by muse, mutect2, varscan2
- TAL2 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.31); catalogued as rs762534217, COSV61883890; called by muse, mutect2, varscan2
- TBC1D16 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs776755761; called by muse, mutect2, varscan2
- TP53 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs147002414, COSV52688422, COSV53250031; called by muse, mutect2, varscan2
- TRIP12 | c.3614G>A p.G1205E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs752869357; called by muse, mutect2, varscan2
- UNC13D | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs143939013; called by muse, mutect2
- USP24 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53779164; called by muse, mutect2, varscan2
- XIRP2 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV54681800, COSV54703198; called by muse, mutect2, varscan2
- YME1L1 | c.1737G>T p.M579I (on ENST00000326799 / NM_139312.3; = p.M522I on NM_014263.4) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100463816; called by muse, mutect2, varscan2
- ZNF317 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs781139661, COSV56108460, COSV56109765; called by muse, mutect2, varscan2
- ZNF354C | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149169026; called by muse, mutect2, varscan2
- ZNF613 | c.1522G>T p.G508W (on ENST00000293471 / NM_001031721.4; = p.G472W on NM_024840.4) | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53272466; called by muse, mutect2, varscan2
- ZNF665 | c.1531G>A p.G511S (on ENST00000600412; = p.G576S on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs372743564; called by muse, mutect2
- ZNF768 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100776155; called by muse, mutect2, varscan2
- ABCA12 | c.1198C>A p.Q400K (on ENST00000272895 / NM_173076.3; = p.Q82K on NM_015657.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCC9 | c.4082G>T p.R1361I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAMTS12 | c.4216C>A p.Q1406K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAMTS12 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS19 | c.2315G>A p.C772Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS2 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADAP2 | c.978G>T p.W326C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- ADGRB3 | c.1103G>T p.R368I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADGRG1 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ADORA2A | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AK9 | c.5705C>G p.S1902C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ALG12 | c.1417C>A p.H473N | Missense Mutation (SNP) | VAF 20/34 reads (59%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.388G>A p.A130T (on ENST00000611781; = p.A74T on NM_052997.2) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AP1G2 | c.1909G>T p.V637F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BEND6 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- C6orf58 | c.150_157del p.Y50* | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- CABIN1 | c.807C>T p.T269= | Splice Region (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- CACNA2D1 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- CCDC40 | c.2142C>A p.S714R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- CDH3 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- CDH9 | c.44T>A p.M15K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CERS4 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CMYA5 | c.3196G>T p.A1066S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- COL7A1 | c.7531G>T p.G2511W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL8A1 | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DCBLD2 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DENND4B | c.3464C>A p.S1155Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DHCR7 | c.1279C>A p.L427M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DIPK1A | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DIRAS2 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by mutect2, varscan2
- DNAH5 | c.6916G>T p.D2306Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DNAJC13 | c.3633G>T p.M1211I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- DR1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DYNC2H1 | c.5044G>T p.G1682* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- EFCAB6 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ERI3 | c.104G>T p.W35L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ERN1 | c.1917C>A p.Y639* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- EXD3 | c.2611C>A p.P871T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FILIP1L | c.1969G>T p.E657* (on ENST00000354552 / NM_182909.3; = p.E417* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- FLG | c.2408C>A p.S803Y | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FOXM1 | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GAD1 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GAS2L2 | c.1554C>A p.S518R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- GPR174 | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSDME | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- IGF1R | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV4-34 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGSF1 | c.1127C>A p.S376* | Nonsense Mutation (SNP) | VAF 34/50 reads (68%) | called by muse, mutect2, varscan2
- IGSF3 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ILF3 | c.2053G>C p.G685R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ILVBL | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS1 | c.4877A>G p.D1626G | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- INTS2 | c.2258C>A p.S753Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KCNJ5 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- KCNJ8 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- KDM6A | c.3742C>A p.Q1248K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- KIF20A | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNDC1 | c.4043T>A p.F1348Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KRT39 | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2
- KRTAP1-3 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- LDLRAD4 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- LRRK2 | c.5129A>C p.N1710T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAB21L1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MAB21L3 | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MAGEL2 | c.3019C>T p.Q1007* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- MARK2 | c.1792C>A p.H598N (on ENST00000402010 / NM_001039469.2; = p.H543N on NM_004954.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MASP1 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- MED12 | c.2640G>T p.M880I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- MET | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MFSD10 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- MICAL2 | c.2105_2106insTT p.E702Dfs*36 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- MMS22L | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MROH5 | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MRPL3 | c.739-1G>T p.X247_splice | Splice Site (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- MRS2 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MTMR10 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MXRA5 | c.7393G>A p.D2465N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MYCBPAP | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MYO3A | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- NAV2 | c.1074C>A p.S358R (on ENST00000396087 / NM_001244963.2; = p.S335R on NM_145117.5) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NEB | c.14631C>A p.I4877= | Splice Region (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- NMB | c.257A>T p.H86L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NPHP4 | c.2859G>T p.Q953H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- NUDCD3 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.611); called by muse, mutect2
- OLFML2B | c.1882G>T p.G628C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPCML | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR2M2 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- OR51G1 | c.805C>A p.H269N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OR6K6 | c.151G>T p.G51C (on ENST00000368144; = p.G27C on NM_001005184.1) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- P3H2 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- PANK2 | c.1247G>A p.G416E (on ENST00000316562 / NM_153638.3; = p.G125E on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX1 | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCDH11X | c.3550C>A p.H1184N | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCNX3 | c.6082C>A p.P2028T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PCYT1B | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PKHD1 | c.6122-1G>T p.X2041_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2
- PLCD4 | c.2012C>T p.T671I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXDC1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- PON3 | c.99A>C p.E33D | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POU2AF1 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PPP1R26 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PPP1R26 | c.1776C>A p.C592* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- PRRC2A | c.3714G>T p.E1238D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- RASGRP1 | c.147G>T p.M49I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS1 | c.2183C>A p.S728Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- RPE | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SCNM1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCNN1G | c.1820C>A p.S607Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SEMA3A | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.971); called by muse, mutect2
- SEZ6L2 | c.1873C>A p.P625T (on ENST00000308713 / NM_001114099.3; = p.P555T on NM_012410.4) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SLC26A3 | c.1270G>C p.V424L | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SLCO1C1 | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SMG7 | c.2944G>T p.E982* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- SOCS4 | c.1001G>T p.R334I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- STAT3 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAT6 | c.1908G>T p.K636N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SUSD2 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- SUSD5 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SYNE1 | c.2739G>T p.K913N (on ENST00000367255 / NM_182961.4; = p.K920N on NM_033071.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- TAT | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.114); called by muse, mutect2
- TENM1 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TENM2 | c.1487G>T p.R496I (on ENST00000518659 / NM_001122679.2; = p.R264I on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX55 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2
- TLN2 | c.6355G>T p.A2119S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TNXB | c.6550T>A p.S2184T (on ENST00000647633; = p.S1937T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TOMM20L | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- TOP2B | c.1830C>A p.F610L (on ENST00000264331 / NM_001330700.2; = p.F605L on NM_001068.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIP11 | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- TRMT44 | c.1661G>T p.C554F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by mutect2, varscan2
- TSKS | c.1690C>A p.L564M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.74340C>A p.Y24780* (on ENST00000591111; = p.Y17356* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- TXNDC16 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- USP26 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTP20 | c.3966G>T p.K1322N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2
- UVSSA | c.1813G>T p.D605Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- VAV1 | c.386T>C p.F129S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- YY1AP1 | c.2107C>T p.P703S (on ENST00000295566 / NM_139118.2; = p.P646S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZBTB41 | c.2368G>T p.V790F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZC3H3 | c.2123G>T p.C708F | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3HAV1 | c.996G>T p.E332D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ZNF518B | c.2291C>A p.A764D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF524 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ZNF552 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AASS | c.81C>T p.A27= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as rs138449792; called by muse, mutect2, varscan2
- AMBRA1 | c.1794C>G p.S598= (on ENST00000458649 / NM_001367468.1; = p.S508= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- ANK2 | c.6642G>A p.P2214= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs775073103, COSV52151339; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- ARPC4 | c.246C>A p.I82= | Silent (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- ASIC4 | c.618C>T p.N206= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs148269786, COSV61733482; called by muse, mutect2, varscan2
- CCT7 | c.816C>T p.N272= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1276688594; called by muse, mutect2, varscan2
- CD163 | c.123C>A p.T41= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs769294403; called by muse, mutect2, varscan2
- CFAP45 | c.114C>A p.L38= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- CPA5 | c.315C>A p.I105= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- DIDO1 | c.3486C>A p.I1162= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- DOCK8 | c.870C>A p.L290= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- DUOXA1 | c.234G>T p.V78= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- EFCAB1 | c.24G>A p.K8= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs372708156; called by muse, mutect2, varscan2
- EFEMP2 | c.198G>A p.K66= | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- ERBB4 | c.1761A>C p.P587= | Silent (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- FAM47C | c.519C>T p.D173= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100792325; called by muse, mutect2, varscan2
- FAM71B | c.1194C>A p.L398= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- FCGBP | c.6606G>A p.A2202= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as rs1271821192, COSV99661121; called by muse, mutect2
- FGL2 | c.678C>A p.T226= | Silent (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2
- GAA | c.2241G>T p.G747= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- GAL3ST4 | c.1167G>T p.L389= | Silent (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- GPR161 | c.504C>T p.S168= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1049033001; called by muse, mutect2, varscan2
- GPR17 | c.696G>A p.P232= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs367931492; called by muse, mutect2, varscan2
- H1-8 | c.564C>A p.P188= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- HSD17B1 | c.714G>A p.A238= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- KCND2 | c.852C>T p.D284= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV58576985; called by muse, mutect2, varscan2
- KCNK5 | c.402C>A p.G134= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1286997453, COSV63988952; called by muse, mutect2, varscan2
- KCNN3 | c.1002C>A p.I334= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- KCNS3 | c.567C>A p.I189= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV58405501, COSV58408795; called by muse, mutect2, varscan2
- KLK1 | c.708C>T p.G236= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- KRTAP10-10 | c.450C>A p.V150= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs587722247, COSV59980497; called by muse, mutect2, varscan2
- LAMA1 | c.7060T>C p.L2354= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- LEXM | c.279C>A p.A93= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- MCF2L | c.1221G>A p.R407= (on ENST00000375608; = p.R375= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- MCF2L2 | c.189C>A p.I63= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- MDN1 | c.15819C>T p.I5273= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV65530286; called by muse, mutect2, varscan2
- MELTF | c.654G>A p.A218= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs755687629, COSV56385993; called by muse, mutect2, varscan2
- MICAL1 | c.3123C>T p.V1041= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs779721061, COSV99237834; called by muse, mutect2, varscan2
- MMP2 | c.33G>A p.T11= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV54600199; called by muse, mutect2, varscan2
- MSN | c.381G>A p.S127= | Silent (SNP) | VAF 14/18 reads (78%) | called by muse, mutect2, varscan2
- NAIF1 | c.270G>T p.V90= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- NFASC | c.2106C>A p.V702= (on ENST00000339876 / NM_001378329.1; = p.V698= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- NOX4 | c.372G>A p.L124= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs745890484, COSV99631073; called by muse, mutect2
- NPAP1 | c.2925C>A p.G975= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- OMG | c.876G>A p.L292= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99907913; called by muse, mutect2, varscan2
- OR1G1 | c.672C>A p.T224= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100187534; called by muse, mutect2, varscan2
- OR4Q3 | c.618G>T p.V206= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV59179530; called by muse, mutect2, varscan2
- OR52D1 | c.735C>A p.G245= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- OR5AR1 | c.828G>T p.V276= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- OVCH2 | c.1123T>C p.L375= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- PATL1 | c.969C>A p.P323= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV55692080; called by muse, mutect2, varscan2
- PCBP3 | c.153G>T p.L51= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- PCDH10 | c.942C>T p.G314= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- PCDHB2 | c.594G>T p.L198= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1515G>A p.A505= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs755191053; called by muse, mutect2, varscan2
- PCOLCE2 | c.324C>A p.G108= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- PDCD6IP | c.699C>T p.Y233= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- PODN | c.1071C>A p.R357= (on ENST00000395871; = p.R309= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- POLE | c.4848G>A p.K1616= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV57680880, COSV57687950; called by muse, mutect2, varscan2
- PRCP | c.90C>A p.G30= | Silent (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- PRELP | c.312C>A p.I104= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs776957308; called by muse, mutect2, varscan2
- PRTG | c.168C>T p.V56= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV66838899; called by muse, mutect2, varscan2
- PSG7 | c.309C>T p.S103= | Silent (SNP) | VAF 56/231 reads (24%) | catalogued as rs1272027067; called by muse, mutect2, varscan2
- RBM41 | c.1185A>G p.Q395= | Silent (SNP) | VAF 20/31 reads (65%) | called by muse, mutect2, varscan2
- RLN1 | c.294G>T p.L98= | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- RND1 | c.441C>A p.I147= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- SLC45A2 | c.1197T>A p.G399= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- SORBS1 | c.2514G>T p.R838= (on ENST00000361941 / NM_001034954.2; = p.R488= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- SPHKAP | c.2571C>T p.S857= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs533054194, COSV60872663; called by muse, mutect2, varscan2
- SRRM1 | c.2310C>A p.P770= | Silent (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- TBX15 | c.657C>A p.L219= (on ENST00000369429 / NM_001330677.2; = p.L113= on NM_152380.3) | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- TFE3 | c.1179G>T p.V393= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- TMEM132D | c.2943C>T p.A981= | Silent (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- TRIM33 | c.3150C>T p.D1050= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- TULP2 | c.1252C>A p.R418= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs376067742; called by muse, mutect2, varscan2
- UNC13C | c.1806G>A p.K602= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs764208672, COSV52923131; called by muse, mutect2, varscan2
- UNC79 | c.4527G>T p.S1509= (on ENST00000393151 / NM_001346218.2; = p.S1332= on NM_020818.5) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV56386673; called by muse, mutect2, varscan2
- ZNF135 | c.174G>A p.P58= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs375491279; called by muse, mutect2, varscan2
- ZNF185 | c.891G>T p.V297= | Silent (SNP) | VAF 46/62 reads (74%) | called by muse, mutect2, varscan2
- CNOT4 | chr7:135384679 C>A | 3'Flank (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- GNG2 | c.-2C>T | 5'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- H2BP2 | chr1:143876077 G>T | 3'Flank (SNP) | VAF 12/80 reads (15%) | catalogued as rs1448841132; called by mutect2, varscan2
- KCNMA1 | c.1928+2371G>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs372858979; called by muse, mutect2, varscan2
- PDZRN4 | c.844-68503C>A | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.*2G>T | 3'UTR (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- TEX2 | chr17:64146128 G>T | 3'Flank (SNP) | VAF 34/96 reads (35%) | catalogued as rs745622177; called by muse, mutect2, varscan2
- TTN | c.10303+2736C>T | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as rs368071705; called by mutect2, varscan2
